Somatic mutation profile of tumor specimen TCGA-NI-A8LF-01A (aliquot TCGA-NI-A8LF-01A-11D-A35Z-10) from TCGA case TCGA-NI-A8LF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 74.4 years (27,162 days).
Specimen TCGA-NI-A8LF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4653f31-912f-42d4-9df3-8afb426b4448.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NI-A8LF-10A (Blood Derived Normal), aliquot TCGA-NI-A8LF-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb1dd57d-1ddb-4114-85c0-b89a80bb0e18

The open-access MAF lists 113 somatic variants for this specimen: 84 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 24, Nonsense Mutation 4, Splice Site 3, Frame Shift Ins 3, Intron 2, RNA 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 81/162 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.5272G>T p.V1758F (on ENST00000272895 / NM_173076.3; = p.V1440F on NM_015657.3) | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55955919, COSV99791004; called by muse, mutect2, varscan2
- ABCB10 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs139689788; called by muse, mutect2, varscan2
- AC004832.3 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.918); catalogued as COSV99840916; called by muse, mutect2, varscan2
- ALLC | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.197); catalogued as COSV52994330, COSV52994675; called by muse, mutect2, varscan2
- AOX1 | c.309+2T>G p.X103_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101022136; called by muse, mutect2, varscan2
- ARHGAP32 | c.4168G>A p.A1390T (on ENST00000310343 / NM_001378025.1; = p.A1041T on NM_014715.4) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100088462; called by muse, mutect2, varscan2
- ATP10B | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756964404, COSV100469587; called by muse, mutect2, varscan2
- AXIN2 | c.893A>G p.N298S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs139274803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCHE | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100012827; called by muse, mutect2, varscan2
- CABIN1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753351557, COSV99573655; called by muse, mutect2, varscan2
- CACNA1A | c.3883A>G p.M1295V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100802866; called by muse, mutect2
- CACNG6 | c.682G>A p.G228S (on ENST00000252729 / NM_145814.1; = p.G157S on NM_031897.2) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as COSV99403540; called by muse, mutect2, varscan2
- CENPF | c.5111T>C p.L1704P | Missense Mutation (SNP) | VAF 98/247 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV100871814; called by muse, mutect2, varscan2
- CEP192 | c.6703G>T p.V2235L | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100381662; called by muse, mutect2, varscan2
- CFAP43 | c.2082T>G p.D694E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99530885; called by muse, mutect2, varscan2
- CLEC1A | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100191591; called by muse, mutect2, varscan2
- COMP | c.1866G>A p.W622* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99721517; called by muse, mutect2, varscan2
- COPZ1 | c.485A>G p.Q162R | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100017674; called by muse, mutect2, varscan2
- CRISP1 | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100236997; called by muse, mutect2, varscan2
- DAB2 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV100298153, COSV57916394; called by muse, mutect2, varscan2
- DNAH5 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV99451857; called by muse, mutect2, varscan2
- EPHX2 | c.667A>T p.N223Y | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV100994668; called by muse, mutect2
- FAM120C | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV100070296; called by muse, mutect2, varscan2
- FAT3 | c.13553C>A p.S4518Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV99968075; called by muse, mutect2, varscan2
- FBH1 | c.2350A>T p.I784F (on ENST00000362091 / NM_178150.3; = p.I835F on NM_032807.4) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as COSV100758836; called by muse, mutect2
- FCRL5 | c.2771A>G p.Y924C | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100709121; called by muse, mutect2, varscan2
- GAREM1 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV99331033; called by muse, mutect2, varscan2
- GCM1 | c.128A>T p.H43L | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV99452511; called by muse, mutect2, varscan2
- GIMAP4 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99750964; called by muse, mutect2, varscan2
- GPC4 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV100895537; called by muse, mutect2, varscan2
- GSTCD | c.164A>T p.E55V | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV100853862; called by muse, mutect2, varscan2
- HOXA4 | c.20T>C p.L7S | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753562339, COSV100415573; called by muse, mutect2, varscan2
- HS3ST3B1 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV100714572; called by muse, mutect2, varscan2
- IGHV1-18 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as rs566019529; called by muse, mutect2, varscan2
- ITGAM | c.2297C>T p.P766L (on ENST00000648685 / NM_001145808.2; = p.P765L on NM_000632.4) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99077059, COSV99792756; called by muse, mutect2, varscan2
- KBTBD12 | c.143T>A p.V48D | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100675474; called by muse, mutect2, varscan2
- KCNH2 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs199472901, CM993712, COSV100060568; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- LIG4 | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV63597836; called by muse, mutect2, varscan2
- MAB21L2 | c.873G>A p.W291* | Nonsense Mutation (SNP) | VAF 52/139 reads (37%) | catalogued as COSV100462321; called by muse, mutect2, varscan2
- MACF1 | c.19017A>T p.E6339D (on ENST00000372915; = p.E4384D on NM_012090.5) | Missense Mutation (SNP) | VAF 25/37 reads (68%) | catalogued as COSV99245703; called by muse, mutect2, varscan2
- MAN2C1 | c.2045A>C p.E682A | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.173); catalogued as COSV99145608; called by muse, mutect2, varscan2
- MAN2C1 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99145611; called by muse, mutect2, varscan2
- MAP1B | c.6950A>T p.D2317V | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99702682; called by muse, mutect2, varscan2
- METTL1 | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV99141566; called by muse, mutect2, varscan2
- MORC3 | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV101264991; called by muse, mutect2, varscan2
- MTMR12 | c.1978A>G p.T660A | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.197); catalogued as COSV99373815; called by muse, mutect2, varscan2
- NUP133 | c.2203A>T p.M735L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99773202; called by muse, mutect2, varscan2
- OCIAD2 | c.67-2A>G p.X23_splice | Splice Site (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99906643; called by muse, mutect2, varscan2
- OGA | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.554); catalogued as COSV100761913; called by muse, mutect2, varscan2
- OR4K2 | c.635T>G p.I212S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs765866386, COSV100064597; called by muse, mutect2, varscan2
- OR6C4 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as COSV101263160; called by muse, mutect2, varscan2
- PEX1 | c.3765G>C p.E1255D | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99952275; called by muse, mutect2, varscan2
- PNMA3 | c.84G>C p.E28D | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV100937639; called by muse, mutect2, varscan2
- POF1B | c.689T>A p.L230Q | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.236); catalogued as COSV99427052; called by muse, mutect2, varscan2
- POFUT1 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100998390; called by muse, mutect2, varscan2
- POU3F2 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100099344; called by muse, mutect2, varscan2
- RUNX1T1 | c.927C>G p.H309Q (on ENST00000265814 / NM_001198628.1; = p.H282Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV56161229, COSV99753438; called by muse, mutect2, varscan2
- SAP130 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52095130; called by muse, mutect2, varscan2
- SCRN3 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867933939, COSV99767375; called by muse, mutect2, varscan2
- SEC16A | c.4894G>T p.D1632Y | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99259405; called by muse, mutect2, varscan2
- SEMA3E | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.894); catalogued as rs777754774, COSV100319116; called by muse, mutect2, varscan2
- SEMA5A | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 234/521 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs139668453; called by muse, mutect2, varscan2
- SEMA6C | c.428C>A p.S143* | Nonsense Mutation (SNP) | VAF 27/195 reads (14%) | catalogued as COSV100501443; called by muse, mutect2, varscan2
- SPTBN2 | c.3227A>T p.D1076V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100019943; called by muse, mutect2, varscan2
- STXBP5 | c.3414+1G>A p.X1138_splice (on ENST00000321680 / NM_001127715.2; = p.X1102_splice on NM_139244.4) | Splice Site (SNP) | VAF 46/63 reads (73%) | catalogued as COSV51652812, COSV99470636; called by muse, mutect2, varscan2
- SYNPO2 | c.1760G>T p.R587I | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100205977, COSV100206059; called by muse, mutect2, varscan2
- SYVN1 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.093); catalogued as COSV99589193; called by muse, mutect2, varscan2
- TACC2 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100553069; called by muse, mutect2, varscan2
- TCF20 | c.4196C>A p.A1399D | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV100166781; called by muse, mutect2, varscan2
- TP53 | c.822_825dup p.A276Lfs*31 | Frame Shift Ins (INS) | VAF 32/51 reads (63%) | catalogued as COSV53366925; called by mutect2, varscan2
- TTF1 | c.836dup p.K280Efs*10 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | catalogued as rs746659855; called by mutect2, varscan2
- TTN | c.60531G>T p.E20177D (on ENST00000591111; = p.E12753D on NM_003319.4) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | PolyPhen possibly damaging (0.487); catalogued as COSV100621257; called by muse, mutect2, varscan2
- UNC93B1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1447462090, COSV99916382; called by muse, mutect2, varscan2
- WDR19 | c.2816A>G p.E939G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV99975702; called by muse, mutect2, varscan2
- ZBTB11 | c.2696G>T p.R899L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV100465653; called by muse, mutect2, varscan2
- ZNF135 | c.1246G>A p.G416R (on ENST00000313434 / NM_001289401.2; = p.G428R on NM_003436.4) | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100536736, COSV100536766; called by muse, mutect2, varscan2
- ZNF443 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100042234; called by muse, mutect2, varscan2
- ZNF479 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 110/260 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV100482887; called by muse, mutect2, varscan2
- ACACA | c.1550A>T p.Y517F | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CROT | c.22del p.S8Qfs*25 | Frame Shift Del (DEL) | VAF 127/390 reads (33%) | called by mutect2, pindel, varscan2
- GNPAT | c.1597C>G p.L533V | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- STARD5 | c.-5_9dup p.A4Tfs*11 | Frame Shift Ins (INS) | VAF 25/71 reads (35%) | called by mutect2, varscan2
- TMEM236 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 171/490 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK3 | c.7902G>A p.V2634= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV99781124; called by muse, mutect2, varscan2
- ARHGAP4 | c.2443C>T p.L815= | Silent (SNP) | VAF 84/109 reads (77%) | catalogued as COSV100509589; called by muse, mutect2, varscan2
- C14orf39 | c.1095G>A p.Q365= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV100407884; called by muse, mutect2, varscan2
- CALCR | c.1434C>T p.I478= (on ENST00000649521 / NM_001164737.2; = p.I462= on NM_001742.4) | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs138214388, COSV64010452; called by muse, mutect2, varscan2
- COG6 | c.780C>A p.V260= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as COSV100743129; called by muse, mutect2, varscan2
- DISC1 | c.393G>A p.R131= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV99698239; called by muse, mutect2, varscan2
- DMBT1 | c.3636C>T p.G1212= (on ENST00000338354 / NM_001377530.1; = p.G713= on NM_004406.3) | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100353594; called by mutect2, varscan2
- EVC2 | c.1578C>T p.H526= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV60404487; called by muse, mutect2, varscan2
- H3-3B | c.90T>G p.A30= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV99638094; called by muse, mutect2, varscan2
- KCNA3 | c.807G>T p.T269= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as COSV100871281, COSV63901228; called by muse, mutect2, varscan2
- LIPE | c.1077G>T p.A359= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV54922503, COSV99734278; called by muse, mutect2, varscan2
- LRP1B | c.360C>T p.C120= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1227880917, COSV101258242; called by muse, mutect2, varscan2
- LYSMD3 | c.525A>T p.T175= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100270459; called by muse, mutect2, varscan2
- MAGEF1 | c.99G>A p.S33= | Silent (SNP) | VAF 43/88 reads (49%) | catalogued as COSV100511012, COSV58633794; called by muse, mutect2, varscan2
- MPP2 | c.93G>T p.L31= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV99290581; called by muse, mutect2, varscan2
- NPR3 | c.48C>T p.G16= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as rs1469089363, COSV99423509; called by muse, mutect2, varscan2
- RINL | c.519C>T p.L173= (on ENST00000591812 / NM_001195833.2; = p.L59= on NM_198445.4) | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV100531253, COSV61575504; called by muse, mutect2
- SCN10A | c.423G>A p.L141= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV71860701; called by muse, mutect2, varscan2
- SHC4 | c.57C>T p.F19= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs761322567, COSV60113227, COSV60114549; called by muse, mutect2, varscan2
- SRD5A2 | c.54C>A p.V18= | Silent (SNP) | VAF 100/398 reads (25%) | catalogued as COSV99252360, COSV99252512; called by muse, varscan2
- SUPT6H | c.4239T>G p.A1413= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs760096029, COSV100112595; called by muse, mutect2, varscan2
- TMEM30B | c.189G>A p.L63= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs765484197, COSV100855749; called by muse, mutect2, varscan2
- TNFRSF19 | c.849C>T p.G283= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs1260754957, COSV99947542; called by muse, mutect2, varscan2
- YTHDF2 | c.1383C>T p.V461= | Silent (SNP) | VAF 52/287 reads (18%) | catalogued as rs1356450077, COSV100863814; called by muse, mutect2, varscan2
- EIF4A2 | c.909+83T>C | Intron (SNP) | VAF 34/73 reads (47%) | catalogued as COSV99961283; called by muse, mutect2, varscan2
- H2BP2 | chr1:143876113 C>A | 3'Flank (SNP) | VAF 60/513 reads (12%) | called by muse, mutect2, varscan2
- PITX2 | c.185-992G>T | Intron (SNP) | VAF 86/411 reads (21%) | catalogued as COSV100146216, COSV100146375; called by muse, mutect2, varscan2
- SSPOP | n.1986C>G | RNA (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100022748; called by muse, varscan2
- SSPOP | n.2058C>T | RNA (SNP) | VAF 10/86 reads (12%) | catalogued as rs1563087909, COSV100022750; called by muse, varscan2
